Gene-level copy-number profile of tumor specimen TCGA-XE-AANX-01A from TCGA case TCGA-XE-AANX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratocarcinoma; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 24.6 years (8,987 days).
Specimen TCGA-XE-AANX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02a90067-bc82-4487-b1d0-736eaf06c0c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/8288d4bc-81cf-4351-ab5b-cd4936308904

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 712; copy number 3: 57; copy number 4: 24,716; copy number 5: 5,568; copy number 6: 18,924; copy number 7: 4,374; copy number 8: 2,903; copy number 9: 736; copy number 10: 34; copy number 11: 15; copy number 12: 1; copy number 13: 772; copy number 14: 59; copy number 16: 4.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,748,514–39,810,097, 2 genes: GLIDR, BX664615.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,621 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,739,506, 15 genes, copy number 9–10: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2.
- chr1:143,784,376–143,797,108, 3 genes, copy number 11: AC239800.3, LINC02591, RNU1-143P.
- chr1:143,905,487–143,934,776, 1 gene, copy number 12 (within-gene range 6–12): AC246680.1.
- chr4:49,486,926–49,589,529, 12 genes, copy number 11: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:37,032–95,683, 3 genes, copy number 9: AC215522.1, AC093627.1, AC093627.6.
- chr7:6,022,247–6,093,085, 5 genes, copy number 10 (within-gene range 8–10): EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1.
- chr7:63,480,598–63,510,165, 3 genes, copy number 10: AC006457.1, SEPTIN7P5, PHKG1P2.
- chr7:157,281,536–157,499,716, 3 genes, copy number 9: AC004975.2, DNAJB6, AC006372.3.
- chr12:66,767–34,249,958, 831 genes, copy number 13–14 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:8,701,461–9,059,060, 11 genes, copy number 10: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4.
- chr21:10,413,477–46,691,226, 730 genes, copy number 9–16 (within-gene range 8–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
